Gene-level copy-number profile of tumor specimen TCGA-CQ-7072-01A from TCGA case TCGA-CQ-7072, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Tongue, NOS; AJCC pathologic stage: Stage II; Tumor grade: G3; Age at diagnosis: 51.6 years (18,841 days).
Specimen TCGA-CQ-7072-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-HNSC.faeb7d58-a156-4ef2-92a4-29f0bec5d6ec.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-CQ-7072-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/1a090790-3435-491c-842c-5f76a4c9fb08

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 10; copy number 1: 1,217; copy number 2: 17,040; copy number 3: 14,188; copy number 4: 11,909; copy number 5: 8,978; copy number 6: 5,461; copy number 7: 866; copy number 8: 42; copy number 15: 11; copy number 24: 5; copy number 34: 87.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-CQ-7072-01A-21D-A30D-01): tumor purity 0.36, ploidy 3.28, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 15,450 genes in 21 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:38,814–94,738,249, 1,648 genes, copy number 5 (broad region; genes not listed).
- chr2:106,697,331–132,671,579, 528 genes, copy number 5–8 (broad region; genes not listed).
- chr3:135,138,469–198,222,513, 1,089 genes, copy number 6–7 (broad region; genes not listed).
- chr4:116,751,473–177,681,381, 779 genes, copy number 5 (within-gene range 1–5) (broad region; genes not listed).
- chr5:58,198–45,895,970, 710 genes, copy number 5 (broad region; genes not listed).
- chr7:70,972–49,259,846, 870 genes, copy number 6 (broad region; genes not listed).
- chr7:52,891,837–62,275,678, 172 genes, copy number 7–34 (broad region; genes not listed).
- chr7:68,149,548–148,420,998, 1,488 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr8:46,028,804–145,066,685, 1,534 genes, copy number 5 (broad region; genes not listed).
- chr12:66,767–46,004,685, 963 genes, copy number 5–6 (broad region; genes not listed).
- chr13:41,955,808–114,337,626, 924 genes, copy number 5–6 (broad region; genes not listed).
- chr14:26,599,755–106,875,071, 1,798 genes, copy number 6 (within-gene range 2–6) (broad region; genes not listed).
- chr16:11,555–19,401,693, 720 genes, copy number 5–6 (within-gene range 4–6) (broad region; genes not listed).
- chr18:47,390–6,415,237, 126 genes, copy number 6–15 (within-gene range 3–15) (broad region; genes not listed).
- chr18:43,499,173–45,068,510, 10 genes, copy number 6 (within-gene range 2–6): AC022743.1, AC083760.1, RNA5SP455, AC110014.1, LINC01478, KRT8P5, MLECP1, SETBP1-DT, SETBP1, AC021766.1.
- chr20:18,379,049–20,056,046, 33 genes, copy number 5: LINC00851, DZANK1, GCNT1P1, RNA5SP476, POLR3F, MIR3192, RPL21P3, RBBP9, RPS19P1, SEC23B, SMIM26, AL121900.1, DTD1, RN7SL638P, RNU6ATAC34P, DUXAP7, DTD1-AS1, EEF1A1P34, LINC00652, LINC00653, SCP2D1-AS1, SCP2D1, AL135936.1, AL136090.2, SLC24A3, AL136090.1, SLC24A3-AS1, AL121830.1, AL121761.1, RIN2, RPL12P12, NAA20, CRNKL1.
- chr20:25,955,795–64,313,132, 930 genes, copy number 6 (broad region; genes not listed).
- chr21:10,328,411–14,658,821, 60 genes, copy number 5 (within-gene range 3–5): AP003900.1, VN1R7P, AF254983.2, BAGE2, AF254983.1, TPTE, CYCSP41, SLC25A15P4, AF254982.1, IGHV1OR21-1, AP001464.1, ANKRD30BP2, RNU6-614P, ZNF355P, AJ239321.1, AJ239318.1, FGF7P2, ANKRD30BP1, MIR3156-3, GTF2IP2, VN1R8P, LINC01674, SNX19P1, OR4K11P, OR4K12P, POTED, RNU6-286P, MIR3118-1, AL050303.2, GRAMD4P1, CXADRP1, AL050303.3, LONRF2P5, MIR8069-2, FEM1AP1, AL050303.1, TERF1P1, FAM207CP, GXYLT1P2, CNN2P7, ZNF114P1, CYP4F29P, SNX18P13, ANKRD20A11P, RHOT1P2, RNU6-954P, NF1P3, PPP6R2P1, FRG2MP, AP001347.1, ANKRD20A18P, RNA5SP488, AP001347.2, LIPI, ERLEC1P1, RBM11, ABCC13, HSPA13, SAMSN1, SAMSN1-AS1.
- chr22:15,290,718–28,008,581, 651 genes, copy number 5 (broad region; genes not listed).
- chr22:27,994,474–28,002,595, 2 genes, copy number 5: AL033538.1, AL033538.2.
- chr22:28,642,979–40,636,719, 415 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 339. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
